Somatic mutation profile of tumor specimen TCGA-S9-A6TW-01A (aliquot TCGA-S9-A6TW-01A-12D-A32B-08) from TCGA case TCGA-S9-A6TW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 40.2 years (14,679 days).
Specimen TCGA-S9-A6TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d197d67e-0aee-4157-a51e-0521ad613f1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TW-10A (Blood Derived Normal), aliquot TCGA-S9-A6TW-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830e9eb2-0819-4cef-8890-033180c1d4c7

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, In Frame Del 3, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 30/101 reads (30%) | hotspot (GDC flag); called by pindel, varscan2
- PIK3CA | c.1033A>T p.N345Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55935593, COSV55957136, COSV56017319; called by muse, mutect2, varscan2
- ADCY4 | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs572851950, COSV100156046; called by muse, mutect2, varscan2
- AHI1 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99661754; called by muse, mutect2, varscan2
- ASTN2 | c.3389C>G p.S1130C (on ENST00000313400 / NM_001365069.1; = p.S1079C on NM_014010.5) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56012674, COSV99939975; called by muse, mutect2, varscan2
- BCORL1 | c.3076G>T p.V1026F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99498172; called by muse, mutect2, varscan2
- CD300LD | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201880339; called by muse, mutect2
- CNOT4 | c.1388A>G p.N463S (on ENST00000315544 / NM_001190848.1; = p.N460S on NM_013316.4) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.099); catalogued as rs745842800, COSV100210948; called by muse, mutect2, varscan2
- CUBN | c.1757A>G p.Q586R | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100911869; called by muse, mutect2, varscan2
- FERMT3 | c.1624C>T p.R542C (on ENST00000279227 / NM_178443.3; = p.R538C on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs760475221, COSV54177371; called by muse, mutect2, varscan2
- HECTD4 | c.12434_12436del p.F4145del | In Frame Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs759649130; called by mutect2, pindel, varscan2
- JARID2 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100521090; called by muse, mutect2, varscan2
- PPM1H | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99955001; called by muse, mutect2, varscan2
- PTEN | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as CM110118, COSV64290316, COSV64291916, COSV64310910; called by muse, mutect2, varscan2
- SIGLEC12 | c.1619C>T p.P540L (on ENST00000291707 / NM_053003.4; = p.P422L on NM_033329.2) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs755424394, COSV52463094; called by muse, mutect2, varscan2
- SLC35F1 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837347; called by muse, mutect2, varscan2
- THEG | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780064961, COSV61072969; called by muse, mutect2, varscan2
- THSD4 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.429); catalogued as COSV99964064; called by muse, mutect2, varscan2
- TPD52 | c.177_179del p.E59del (on ENST00000379097 / NM_001025252.3; = p.E19del on NM_005079.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs750865439; called by pindel, varscan2
- UBP1 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs188688575; called by muse, mutect2, varscan2
- ZNF175 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99219220; called by muse, mutect2
- CIC | c.451dup p.A151Gfs*9 | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- MYH10 | c.44_45del p.F15Cfs*14 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel
- PIGU | c.389del p.P130Lfs*9 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- COL24A1 | c.2865T>A p.P955= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CPNE9 | c.477G>A p.L159= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV99807975; called by muse, mutect2, varscan2
- GSN | c.1134G>A p.S378= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs145170518, COSV100375618; called by muse, mutect2, varscan2
- GUCY2C | c.1551T>C p.D517= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99663105; called by muse, mutect2, varscan2
- HHAT | c.1311G>A p.S437= | Silent (SNP) | VAF 117/362 reads (32%) | catalogued as rs761262503, COSV54792842, COSV99801990; called by muse, mutect2, varscan2
- MAD1L1 | c.856C>T p.L286= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as COSV99764857; called by muse, mutect2, varscan2
- RASSF1 | c.879G>A p.G293= (on ENST00000357043 / NM_170714.2; = p.G289= on NM_007182.5) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99222616; called by muse, mutect2, varscan2
- RNPS1 | chr16:2271812 G>A | 5'Flank (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
